Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A114, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A114-01A (Primary Tumor).

[page 1 of 4]
1CD-0-3

Carcinoma, hepatocellular, Nos 8170/3

Site: liver c22-0 1/24/11 *sw*

Patient Key:

Surgical date:

TISSUE¹ DESCRIPTION:

A1 A2 A3 A4 A5 A6 A7 A8 A9 A10

Right lobe liver 17.0 x 15.0 x 7.5 cm with gallbladder (9.5 x 5.4 cm) together weighing 1,015 grams.

DIAGNOSIS:

Liver, right lobe, excision: Grade 3 (of 4) hepatocellular carcinoma, usual type, forming a single mass (3.1 x 2.4 x 2.3 cm). The tumor is located in the right lobe. The hepatic capsule is free of tumor. The surgical margins are free of tumor (free by 0.5 cm). Extratumoral vascular invasion is identified. The tumor is not encapsulated, infiltration of parenchyma being of pushing type. No lymph nodes are identified. The gallbladder shows cholesterolosis, otherwise unremarkable. Non-neoplastic hepatic parenchyma will be assessed in permanent sections.

ADDENDUM:

Non-neoplastic liver shows chronic hepatitis, consistent with hepatitis C virus (HCV) infection, mildly active (grade 2 of 4), with portal and periportal fibrosis (stage 2).

Seen in consultation with

[page 2 of 4]
1CD-0-3

Carcinoma, hepatocellular, NOS 8170/3

Site: liver C22.0 1/24/11 *fw*

Patient Key: . . .

Surgical date: . . .

TISSUE DESCRIPTION:

A1 A2 A3 A4 A5 A6 A7 A8 A9 A10

Right lobe liver 17.0 x 15.0 x 7.5 cm with gallbladder (9.5 x 5.4 cm) together weighing 1,015 grams.

DIAGNOSIS:

Liver, right lobe, excision: Grade 3 (of 4) hepatocellular carcinoma, usual type, forming a single mass (3.1 x 2.4 x 2.3 cm). The tumor is located in the right lobe. The hepatic capsule is free of tumor. The surgical margins are free of tumor (free by 0.5 cm). Extratumoral vascular invasion is identified. The tumor is not encapsulated, infiltration of parenchyma being of pushing type. No lymph nodes are identified. The gallbladder shows cholesterolosis, otherwise unremarkable. Non-neoplastic hepatic parenchyma will be assessed in permanent sections.

ADDENDUM:

Non-neoplastic liver shows chronic hepatitis, consistent with hepatitis C virus (HCV) infection, mildly active (grade 2 of 4), with portal and periportal fibrosis (stage 2).

Seen in consultation with . . .

[page 3 of 4]
Liver • Digestive System CAP Approved

* Data elements *with asterisks* are *not required* for accreditation purposes for the Commission on Cancer. These elements may be clinically important, but are not yet validated or regularly used in patient management. Alternatively, the necessary data may not be available to the pathologist at the time of pathologic assessment of this specimen.

LIVER: Resection

Patient name: (to be de-identified)

Patient Key:

Surgical pathology number:

Surgery Date:

MACROSCOPIC

Specimen Type

- ☒ Right lobectomy
☐ Extended right lobectomy
☐ Medial segmentectomy
☐ Left lateral segmentectomy
☐ Total left lobectomy
☐ Explanted liver
☐ Other (specify): _____
☐ Not specified

Focality

- ☒ Solitary (specify location): right lobe.
☐ Multiple (specify location): _____

Tumor Size

Greatest dimension: 3.1 cm

*Additional dimensions: 2.4 x 2.3 cm

☐ Cannot be determined (see Comment)

MICROSCOPIC

Histologic Type

- ☒ Hepatocellular carcinoma
☐ Fibrolamellar hepatocellular carcinoma variant (specify): _____
☐ Combined hepatocellular and cholangiocarcinoma
☐ Cholangiocarcinoma, intrahepatic
☐ Bile duct cystadenocarcinoma
☐ Undifferentiated carcinoma
☐ Other (specify): _____
☐ Carcinoma, type cannot be determined

Histologic Grade

- ☐ Not applicable
☐ GX: Cannot be assessed
☐ GI: Well differentiated
☐ GII: Moderately differentiated
☒ GIII: Poorly differentiated
☐ GIV: Undifferentiated/anaplastic
☐ Other (specify): _____

[page 4 of 4]
Pathologic Staging (pTNM)**Primary Tumor (pT)**☐ pTX: Cannot be assessed☐ pT0: No evidence of primary tumor☐ pT1: Solitary tumor with no vascular invasion☒ pT2: Solitary tumor with vascular invasion or multiple tumors none more than 5 cm☐ pT3: Multiple tumors more than 5 cm or tumor involving a major branch of the portal or hepatic vein(s)☐ pT4: Tumor(s) with direct invasion of adjacent organs other than the gallbladder or perforation of visceral peritoneum**Regional Lymph Nodes (pN)**☒ pNX: Cannot be assessed☐ pN0: No regional lymph node metastasis☐ pN1: Regional lymph node metastasisSpecify: Number examined: Number involved: **Distant Metastasis (pM)**☒ pMX: Cannot be assessed☐ pM1: Distant metastasis*Specify site(s), if known: **Margins (check all that apply)****Parenchymal Margin**☐ Cannot be assessed☒ Uninvolved by invasive carcinomaDistance of invasive carcinoma from closest margin: 5.0 mmSpecify margin: ☐ Involved by invasive carcinoma**Bile Duct Margin (Cholangiocarcinoma Only)**☐ Cannot be assessed☐ Uninvolved by invasive carcinoma* ☐ Carcinoma in situ absent* ☐ Carcinoma in situ present☐ Involved by invasive carcinoma**Other Margin**Specify margin: ☐ Cannot be assessed☐ Uninvolved by invasive carcinoma☐ Involved by invasive carcinoma***Venous (Large Vessel) Invasion (V)*** ☐ Absent* ☒ Present* ☒ Indeterminate***Additional Pathologic Findings (check all that apply)*** ☐ None identified* ☐ Hepatocellular dysplasia* ☐ Ductal dysplasia* ☒ Cirrhosis/fibrosis (stage 2)* ☐ Iron overload* ☒ Hepatitis (specify type): Chronic Hepatitis C infection* ☐ Other (specify):

Source: NCI Genomic Data Commons file 68e5d968-d20a-40f7-bef8-78e97c782ef6 (TCGA-DD-A114.BACAFF9B-FAC1-49A8-8C56-A0A26794AA1E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).